Gene-level copy-number profile of tumor specimen MP2PRT-PAUCUZ-TMP1-A from MP2PRT case MP2PRT-PAUCUZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,920 days).
Specimen MP2PRT-PAUCUZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2fb6e9ec-e4f7-4adf-ab76-a846760fbf2c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUCUZ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/9e212cfc-3e86-4cac-a1b8-302d4489d8a3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 93; copy number 1: 101; copy number 2: 42,674; copy number 3: 14,769; copy number 4: 743; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,244,781–89,295,455, 7 genes (within-gene range 0–2): IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36.
- chr7:38,256,337–38,256,396, 1 gene (within-gene range 0–1): TRGJP2.
- chr8:64,091–79,775, 2 genes: AC144568.1, AC144568.2.
- chr9:42,636,788–42,714,539, 3 genes: BX088651.3, FGF7P4, BX664718.1.
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr14:105,851,705–106,269,140, 70 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:42,579,414–42,626,813, 2 genes, copy number 5: BX088651.2, FGF7P5.
- chr10:79,661,394–79,826,594, 1 gene, copy number 5 (within-gene range 3–5): NUTM2B-AS1.
- chr10:79,703,227–79,714,681, 1 gene, copy number 5: NUTM2B.

Autosomal genes at a single copy (total copy number 1): 101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
